TARGET case TARGET-40-NAAWGA — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms.
https://portal.gdc.cancer.gov/cases/b7f11ab7-4875-5f63-a11d-9bc6f5f7e8d5

Biospecimens (1 sample)
- Sample TARGET-40-NAAWGA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
